Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-A9RL, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-A9RL-01A (Primary Tumor).

SPECIMEN

Bladder TURT.

CLINICAL DETAILS

Previous G3 pTa bladder tumour. Now 2 lesions.

1 papillary at bladder neck and 1 at the dome of the bladder.

MACROSCOPY

Four pieces of tissue, the largest 6 mm.

MICROSCOPY

Please note only one specimen received.

Grade:

3 poorly differentiated

Growth pattern:

Papillary

Type:

Transitional cell carcinoma.

Muscularis propria:

Present

Stromal invasion:

The basal part of the tumour is fragmented, with individual cells appearing to invade the superficial part of the lamina propria; this may be artefactual but early stromal invasion cannot be excluded.

Vascular channel invasion:

Not identified

Background urothelium:

Flat urothelium is present which is not dysplastic.

SUMMARY

Bladder, transitional cell carcinoma G3, equivocal stage.

Pathologists -

DR

CALL ICD-O-3
path Carcinoma, urothelial NOS 8120/3
Carcinoma, transitional cell NOS 8120/3
Site: 4 Bladder NOS C67.9
JW 5/2/14

Prior Malignancy History	bladder	✓

Source: NCI Genomic Data Commons file d2cfae29-394c-4b44-90c0-f215f745d700 (TCGA-ZF-A9RL.EC382266-E28D-4F67-B363-84425688F82F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).